Somatic mutation profile of tumor specimen C3N-01714-02 (aliquot CPT0124360006) from CPTAC case C3N-01714, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.4 years (23,163 days).
Specimen C3N-01714-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc95a596-b82a-4ab0-9895-25fb615ee5f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01714-31 (Blood Derived Normal), aliquot CPT0124390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9465638-49d6-4a2a-8b97-21c25cd33dfd

The open-access MAF lists 45 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Nonsense Mutation 3, Splice Region 1, Frame Shift Del 1, 5'Flank 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 36/304 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 42/382 reads (11%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABRAXAS2 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs968863430, COSV53716833; called by muse, mutect2
- ADCK5 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 23/481 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs1206845562; called by muse, mutect2
- ADGRB3 | c.1445G>C p.C482S | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101002291; called by muse, mutect2
- ALX4 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100241231; called by muse, mutect2
- ASTL | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.737); catalogued as rs373382016; called by muse, mutect2
- BMP7 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 49/502 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs371762840; called by muse, mutect2
- BNC2 | c.1509G>T p.R503S | Missense Mutation (SNP) | VAF 24/499 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV66149783; called by muse, mutect2
- EVX2 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs765774536, COSV57963877; called by muse, mutect2
- LCE3D | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 47/540 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs749727744, COSV100909887; called by muse, mutect2
- PCDHA11 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 22/525 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100247543; called by muse, mutect2
- PLXNB2 | c.3845A>G p.D1282G | Missense Mutation (SNP) | VAF 53/507 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100833925; called by muse, mutect2, varscan2
- POU3F2 | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60408656, COSV60409574; called by muse, mutect2, varscan2
- RPS6KA3 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs980055137; called by muse, mutect2, varscan2
- SGK2 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs149168513; called by muse, mutect2
- TRIM72 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 8/192 reads (4%) | catalogued as rs1356384611; called by muse, mutect2
- CDC42BPB | c.2526G>A p.M842I | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- CNTLN | c.1767G>T p.M589I | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2
- DCAF8L2 | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); called by muse, mutect2
- DYNC2I1 | c.1526A>C p.D509A | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.149); called by muse, mutect2
- FAM107A | c.327+5G>T | Splice Region (SNP) | VAF 24/462 reads (5%) | called by muse, mutect2
- GALNT7 | c.1602G>A p.W534* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | called by mutect2, varscan2
- KIF5C | c.713A>G p.K238R | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- KLB | c.1473A>T p.K491N | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.258); called by muse, mutect2
- PCDHA8 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 43/780 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); called by muse, mutect2
- RECQL4 | c.2452del p.L818Cfs*25 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | called by mutect2, pindel, varscan2
- SMG1 | c.3928G>A p.D1310N | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2
- SPICE1 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2
- SYNM | c.1811G>C p.G604A | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.085); called by muse, mutect2
- TRPS1 | c.222C>G p.D74E (on ENST00000220888 / NM_001330599.2; = p.D87E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/433 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.301); called by muse, mutect2
- WDR5B | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 25/343 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- ZNF831 | c.3951A>C p.R1317S | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2
- CYP26B1 | c.345C>T p.T115= | Silent (SNP) | VAF 7/169 reads (4%) | catalogued as COSV50011727; called by muse, mutect2
- DNAH9 | c.9729G>A p.P3243= | Silent (SNP) | VAF 27/424 reads (6%) | catalogued as rs149731222; called by muse, mutect2
- IRX1 | c.624C>T p.S208= | Silent (SNP) | VAF 13/378 reads (3%) | catalogued as COSV100116237, COSV57361038; called by muse, mutect2
- KIF21B | c.1497C>T p.N499= | Silent (SNP) | VAF 8/222 reads (4%) | catalogued as rs1422871934; called by muse, mutect2
- LMBRD2 | c.1299C>T p.I433= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs187816551, COSV56950263; called by muse, mutect2, varscan2
- LPA | c.2736G>A p.A912= | Silent (SNP) | VAF 23/793 reads (3%) | catalogued as rs1344439639; called by muse, mutect2
- PCDHA13 | c.1302G>A p.S434= | Silent (SNP) | VAF 25/536 reads (5%) | catalogued as COSV56496912; called by muse, mutect2
- RAB11FIP2 | c.444C>T p.T148= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs188765663, COSV62924859; called by muse, mutect2, varscan2
- TTN | c.34761T>C p.S11587= (on ENST00000591111; = p.S10660= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/234 reads (8%) | catalogued as rs773883685; ClinVar: likely benign; called by muse, mutect2
- CCDC33 | c.2139+58C>T | Intron (SNP) | VAF 32/225 reads (14%) | catalogued as rs528890370; called by muse, mutect2, varscan2
- ERGIC3 | chr20:35559187 G>A | 3'Flank (SNP) | VAF 14/164 reads (9%) | catalogued as rs937707491; called by muse, mutect2
- YAF2 | chr12:42238627 G>T | 5'Flank (SNP) | VAF 13/156 reads (8%) | catalogued as rs1048682127; called by muse, mutect2
